Somatic mutation profile of tumor specimen C3N-03417-01 (aliquot CPT0247880006) from CPTAC case C3N-03417, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 67.8 years (24,766 days).
Specimen C3N-03417-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb2e8b09-17c9-49df-8e3c-9f4b2fb8e772.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03417-31 (Blood Derived Normal), aliquot CPT0247900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a330a97f-e659-4eed-83d3-dcb7a199816d

The open-access MAF lists 69 somatic variants for this specimen: 47 protein-altering or splice-affecting, 12 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 12, Intron 7, Nonsense Mutation 4, Splice Region 2, Splice Site 2, RNA 2, In Frame Del 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 126/317 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DIS3 | c.2338A>G p.R780G | Missense Mutation (SNP) | VAF 62/142 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66708015; called by muse, mutect2, varscan2
- PIK3CA | c.3132T>A p.N1044K | Missense Mutation (SNP) | VAF 23/51 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen possibly damaging (0.63); catalogued as COSV55875087, COSV55897116; called by muse, mutect2, varscan2
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 64/71 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 230/823 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387356833, COSV55945226, COSV55959906; called by muse, mutect2, varscan2
- ABCD1 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 125/311 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs782159028, COSV54387281; called by muse, mutect2, varscan2
- ARID1A | c.6228C>G p.Y2076* | Nonsense Mutation (SNP) | VAF 310/368 reads (84%) | catalogued as COSV61371566; called by muse, mutect2, varscan2
- ATP2A3 | c.1934C>T p.T645M | Missense Mutation (SNP) | VAF 162/388 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as rs373841113; called by muse, mutect2, varscan2
- CCL3 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 140/350 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1251992195; called by muse, mutect2, varscan2
- CHD4 | c.2885G>A p.R962H (on ENST00000357008 / NM_001363606.2; = p.R975H on NM_001273.5) | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58896611, COSV58901386; called by muse, mutect2, varscan2
- CYP1B1 | c.350G>C p.R117P | Missense Mutation (SNP) | VAF 320/708 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM066032; called by muse, mutect2, varscan2
- DHODH | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 149/412 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV54662802; called by muse, mutect2, varscan2
- DSEL | c.2593G>T p.V865F | Missense Mutation (SNP) | VAF 154/369 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV100025727; called by muse, mutect2, varscan2
- EHHADH | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs145907786; called by muse, mutect2, varscan2
- ESS2 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768922267, COSV52817239; called by muse, varscan2
- FAM86B1 | c.790+7C>T | Splice Region (SNP) | VAF 396/1818 reads (22%) | catalogued as rs763703194; called by muse, mutect2, varscan2
- FAM9A | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.009); catalogued as COSV101121309; called by muse, mutect2
- GSG1L | c.526G>A p.A176T (on ENST00000447459 / NM_001109763.2; = p.A21T on NM_144675.2) | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs762645029, COSV101093972; called by muse, mutect2, varscan2
- HGF | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 99/308 reads (32%) | catalogued as COSV55950843; called by muse, mutect2, varscan2
- IGHV3-48 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 82/289 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.848); catalogued as rs782063685; called by muse, mutect2, varscan2
- LZTR1 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 91/236 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1309568769, COSV53145725, COSV99302293; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHIP | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1562217773, COSV51507630; called by muse, mutect2
- PKHD1 | c.6797C>T p.A2266V | Missense Mutation (SNP) | VAF 109/248 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs755286726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.302T>G p.I101S | Missense Mutation (SNP) | VAF 296/356 reads (83%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as CD110165, CM110135, CX983284, COSV64289692, COSV64297668, COSV64311547; called by muse, mutect2, varscan2
- SEMA4G | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 91/326 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as rs751304450, COSV52966712; called by muse, mutect2, varscan2
- SIN3A | c.1819G>T p.E607* | Nonsense Mutation (SNP) | VAF 57/152 reads (38%) | catalogued as COSV100845018, COSV64583660; called by muse, mutect2, varscan2
- TFR2 | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 92/150 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746407340, CM136281; called by muse, mutect2, varscan2
- THBS3 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 83/180 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.029); catalogued as COSV64250206, COSV64250525; called by muse, mutect2, varscan2
- ZNF45 | c.486A>C p.K162N | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV99524007; called by muse, mutect2, varscan2
- AL592490.1 | c.2236C>T p.Q746* | Nonsense Mutation (SNP) | VAF 85/238 reads (36%) | called by muse, mutect2, varscan2
- ANAPC1 | c.1949G>A p.G650E | Missense Mutation (SNP) | VAF 83/481 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ATP8B3 | c.2387T>C p.L796P | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- BRD8 | c.642+2T>A p.X214_splice | Splice Site (SNP) | VAF 45/111 reads (41%) | called by muse, mutect2
- BSN | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 104/192 reads (54%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH23 | c.3211G>A p.E1071K | Missense Mutation (SNP) | VAF 109/175 reads (62%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.96); called by muse, varscan2
- FBXO15 | c.152del p.A51Vfs*3 | Frame Shift Del (DEL) | VAF 165/433 reads (38%) | called by mutect2, pindel, varscan2
- GLRA1 | c.766T>C p.Y256H | Missense Mutation (SNP) | VAF 190/519 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GTF2F1 | c.35C>T p.T12I | Missense Mutation (SNP) | VAF 101/227 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- KAT6B | c.565A>G p.S189G | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE6B | c.2021+5G>A | Splice Region (SNP) | VAF 86/215 reads (40%) | called by muse, mutect2, varscan2
- POU3F3 | c.278A>C p.H93P | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- PPP6R3 | c.2038+2dup p.X680_splice (on ENST00000393800 / NM_001352375.2; = p.X600_splice on NM_018312.5) | Splice Site (INS) | VAF 47/130 reads (36%) | called by mutect2, pindel, varscan2
- PRDM4 | c.1163G>A p.C388Y | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- SIN3A | c.1127_1156del p.F376_S385del | In Frame Del (DEL) | VAF 60/153 reads (39%) | called by mutect2, pindel
- SRPK2 | c.1331A>G p.K444R | Missense Mutation (SNP) | VAF 172/278 reads (62%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WNT9B | c.341A>G p.K114R | Missense Mutation (SNP) | VAF 86/245 reads (35%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- ZBTB7B | c.1418C>T p.P473L (on ENST00000292176; = p.P507L on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 187/432 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ABCG5 | c.1410C>T p.H470= | Silent (SNP) | VAF 264/1225 reads (22%) | catalogued as rs369709495; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAMDEC1 | c.720G>A p.L240= | Silent (SNP) | VAF 42/90 reads (47%) | called by muse, mutect2, varscan2
- DEPDC1 | c.480C>T p.G160= | Silent (SNP) | VAF 69/84 reads (82%) | catalogued as rs561724598, COSV63958547; called by muse, mutect2, varscan2
- FUT2 | c.231C>T p.G77= | Silent (SNP) | VAF 147/364 reads (40%) | catalogued as rs201304120, COSV67179297; called by muse, mutect2, varscan2
- GRAMD1B | c.216C>T p.S72= | Silent (SNP) | VAF 120/304 reads (39%) | called by muse, mutect2, varscan2
- KIRREL1 | c.294C>T p.Y98= | Silent (SNP) | VAF 157/421 reads (37%) | catalogued as rs776450821, COSV63287401; called by muse, mutect2, varscan2
- MUC12 | c.8698C>T p.L2900= (on ENST00000379442; = p.L2757= on NM_001164462.1) | Silent (SNP) | VAF 142/3211 reads (4%) | called by muse, mutect2
- NAA25 | c.1263G>A p.T421= | Silent (SNP) | VAF 313/569 reads (55%) | catalogued as COSV55704911; called by muse, mutect2, varscan2
- SBK2 | c.678C>T p.P226= | Silent (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- TTC30B | c.1452C>T p.P484= | Silent (SNP) | VAF 85/213 reads (40%) | catalogued as rs1208147475; called by muse, mutect2, varscan2
- YME1L1 | c.696G>A p.A232= (on ENST00000326799 / NM_139312.3; = p.A175= on NM_014263.4) | Silent (SNP) | VAF 84/286 reads (29%) | catalogued as rs762820014, COSV100463606, COSV58758355; called by muse, mutect2, varscan2
- ZFPM1 | c.1038G>A p.L346= | Silent (SNP) | VAF 95/212 reads (45%) | called by muse, mutect2, varscan2
- AP000842.1 | n.459G>A | RNA (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- BRD9 | c.52+47A>T | Intron (SNP) | VAF 110/130 reads (85%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.2922-24G>A | Intron (SNP) | VAF 62/260 reads (24%) | catalogued as rs376685731; called by muse, mutect2, varscan2
- DENND10P1 | n.720G>A | RNA (SNP) | VAF 210/526 reads (40%) | called by muse, mutect2, varscan2
- DUOX2 | c.2851+25G>A | Intron (SNP) | VAF 96/222 reads (43%) | catalogued as rs370200906; called by muse, mutect2, varscan2
- EXD2 | c.1050-32C>T | Intron (SNP) | VAF 128/444 reads (29%) | catalogued as rs900710677; called by muse, mutect2, varscan2
- FAM53A | c.883-2620C>T | Intron (SNP) | VAF 163/197 reads (83%) | catalogued as rs563668707; called by muse, mutect2, varscan2
- KDM5C | c.*181C>T | 3'UTR (SNP) | VAF 11/111 reads (10%) | called by muse, mutect2, varscan2
- SNPH | c.-47-15G>T | Intron (SNP) | VAF 51/170 reads (30%) | catalogued as rs373921517; called by muse, mutect2, varscan2
- Z96074.1 | n.151+3049A>T | Intron (SNP) | VAF 53/135 reads (39%) | catalogued as COSV101004155; called by muse, mutect2, varscan2
